Gene-level copy-number profile of tumor specimen TCGA-29-1776-01A from TCGA case TCGA-29-1776, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.0 years (23,016 days).
Specimen TCGA-29-1776-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.655c6e8d-4972-44cb-84e1-60197b73fb58.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1776-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/707faf52-ff33-40a3-ad62-4a117410b809

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,102; copy number 2: 34,719; copy number 3: 6,003; copy number 4: 1,321; copy number 5: 596; copy number 6: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1776-01A-01D-0577-01): tumor purity 0.88, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 671 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:170,115,636–176,845,601, 129 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:131,904,093–139,463,016, 75 genes, copy number 6 (broad region; genes not listed).
- chr11:79,191,558–108,959,797, 466 genes, copy number 5 (broad region; genes not listed).
- chr11:109,005,517–109,005,623, 1 gene, copy number 5: RNU6-654P.

Autosomal genes at a single copy (total copy number 1): 16,205. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
